Somatic mutation profile of tumor specimen TCGA-ND-A4W6-01A (aliquot TCGA-ND-A4W6-01A-11D-A28R-08) from TCGA case TCGA-ND-A4W6, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mullerian mixed tumor; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC; Age at diagnosis: 68.0 years (24,835 days).
Specimen TCGA-ND-A4W6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a3a40aae-6b8e-4bf5-9fe1-4055f207a38a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ND-A4W6-10A (Blood Derived Normal), aliquot TCGA-ND-A4W6-10A-01D-A28U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/01fbbbf7-477b-40e2-9111-c461cc618982

The open-access MAF lists 91 somatic variants for this specimen: 67 protein-altering or splice-affecting, 21 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 58, Silent 21, Nonsense Mutation 4, Frame Shift Del 3, Intron 3, Splice Site 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1810T>C p.C604R | Missense Mutation (SNP) | VAF 7/27 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.657); catalogued as COSV55888333; called by muse, mutect2, varscan2
- TP53 | c.722C>A p.S241Y | Missense Mutation (SNP) | VAF 27/52 reads (52%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934573, CM1212186, CM920673, COSV52661688, COSV52662386, COSV52713934, COSV52760886; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AKAP6 | c.5729C>T p.P1910L | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs771986930; called by mutect2, varscan2
- ALG1 | c.209-1G>T p.X70_splice | Splice Site (SNP) | VAF 7/90 reads (8%) | catalogued as CS166929; called by muse, mutect2
- ARID1A | c.6076C>T p.Q2026* | Nonsense Mutation (SNP) | VAF 47/97 reads (48%) | catalogued as COSV61374555; called by muse, mutect2, varscan2
- B4GALT3 | c.551G>A p.R184H | Missense Mutation (SNP) | VAF 40/79 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs751401924; called by muse, mutect2, varscan2
- BSN | c.478C>G p.Q160E | Missense Mutation (SNP) | VAF 51/94 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as COSV56513924; called by muse, mutect2, varscan2
- CACNA1E | c.3179C>T p.T1060M | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs746583309, COSV62399684; called by mutect2, varscan2
- CD74 | c.674C>T p.P225L | Missense Mutation (SNP) | VAF 23/218 reads (11%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.981); catalogued as rs529228293, COSV50534132; called by muse, mutect2, varscan2
- CHRNA2 | c.710C>T p.T237M | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.75); catalogued as rs140350483; called by muse, mutect2, varscan2
- CYP2U1 | c.1117G>A p.D373N | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.159); catalogued as rs751335350; called by muse, mutect2, varscan2
- EPHA5 | c.1034G>A p.R345K | Missense Mutation (SNP) | VAF 31/122 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV56640223, COSV99900167; called by muse, mutect2, varscan2
- FAT3 | c.4467G>C p.E1489D | Missense Mutation (SNP) | VAF 46/169 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); catalogued as COSV53097474; called by muse, mutect2, varscan2
- FGF6 | c.251G>A p.R84Q | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs762919183, COSV99960129; called by muse, mutect2, varscan2
- GAL3ST3 | c.455G>A p.R152H | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1433790903; called by muse, mutect2, varscan2
- HMGCS2 | c.562C>T p.R188C | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1227400362; called by muse, mutect2
- LRRC7 | c.488A>T p.N163I (on ENST00000651989 / NM_001370785.2; = p.N130I on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50422745; called by muse, varscan2
- LZTR1 | c.729C>G p.F243L | Missense Mutation (SNP) | VAF 94/124 reads (76%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as COSV53152585; called by muse, mutect2, varscan2
- MFN1 | c.1255C>T p.R419* | Nonsense Mutation (SNP) | VAF 8/64 reads (13%) | catalogued as rs1456956963; called by muse, mutect2, varscan2
- MYH2 | c.3359G>A p.R1120H | Missense Mutation (SNP) | VAF 40/62 reads (65%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.957); catalogued as rs752746936, COSV55433509; called by muse, mutect2, varscan2
- NRXN1 | c.656C>T p.A219V | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1360707101, COSV101279035, COSV68013853; called by muse, mutect2, varscan2
- NRXN2 | c.5057C>T p.A1686V | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as rs1217710526, COSV55463667; called by muse, mutect2, varscan2
- OS9 | c.1681G>A p.E561K | Missense Mutation (SNP) | VAF 41/130 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.307); catalogued as rs770733178; called by muse, mutect2, varscan2
- PARP2 | c.458G>A p.R153Q | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763406681; called by muse, mutect2, varscan2
- PREX1 | c.2330G>A p.R777Q | Missense Mutation (SNP) | VAF 66/194 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.044); catalogued as rs368578845; called by muse, mutect2, varscan2
- PTCRA | c.217G>A p.A73T | Missense Mutation (SNP) | VAF 19/166 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.215); catalogued as rs1050986779; called by muse, mutect2, varscan2
- RAP1A | c.35G>A p.G12E | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62727539; called by muse, mutect2, varscan2
- SAMD11 | c.1678G>A p.E560K | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as rs1447814461, COSV58990044; called by muse, mutect2, varscan2
- SLC25A51 | c.136G>A p.A46T | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs370897815; called by muse, mutect2, varscan2
- SPATA31D1 | c.2792C>A p.S931* | Nonsense Mutation (SNP) | VAF 9/38 reads (24%) | catalogued as COSV61195645; called by muse, mutect2, varscan2
- SYNE1 | c.508C>T p.R170W (on ENST00000367255 / NM_182961.4; = p.R177W on NM_033071.3) | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777175001, COSV54897233; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TAF7L | c.1024G>C p.D342H | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.741); catalogued as COSV61257413; called by muse, mutect2, varscan2
- TCHH | c.5297G>A p.R1766H | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.893); catalogued as COSV64276176; called by muse, mutect2, varscan2
- TMUB2 | c.959G>A p.G320E (on ENST00000538716 / NM_001353177.2; = p.G300E on NM_024107.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 46/163 reads (28%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.573); catalogued as rs753215788; called by muse, mutect2, varscan2
- TRPM2 | c.1649C>T p.A550V | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as rs1256441456; called by muse, mutect2, varscan2
- YTHDC2 | c.1304T>C p.V435A | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as rs900169621; called by muse, mutect2, varscan2
- ADCY10 | c.4177del p.Y1393Ifs*34 | Frame Shift Del (DEL) | VAF 6/50 reads (12%) | called by pindel, varscan2
- AKAP8 | c.1326G>C p.K442N | Missense Mutation (SNP) | VAF 28/49 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- CABS1 | c.733A>C p.S245R | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- CDH16 | c.1997C>G p.T666S | Missense Mutation (SNP) | VAF 51/87 reads (59%) | SIFT tolerated (0.13); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- CLASRP | c.587A>T p.D196V | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT deleterious (0.03); called by muse, mutect2, varscan2
- CLBA1 | c.447T>G p.I149M | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- FLNC | c.1930_1936del p.C644Mfs*25 | Frame Shift Del (DEL) | VAF 31/210 reads (15%) | called by mutect2, pindel*
- FRMPD1 | c.3727G>T p.D1243Y | Missense Mutation (SNP) | VAF 43/106 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- GABRA6 | c.64G>T p.E22* | Nonsense Mutation (SNP) | VAF 21/63 reads (33%) | called by muse, mutect2, varscan2
- GRM4 | c.2114G>A p.S705N | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- HGF | c.349G>C p.D117H | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2
- ITPKB | c.1309T>A p.W437R | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated, low confidence (0.97); PolyPhen benign (0); called by muse, mutect2, varscan2
- KLF6 | c.742del p.T248Pfs*32 | Frame Shift Del (DEL) | VAF 35/86 reads (41%) | called by mutect2, pindel, varscan2
- LRP1 | c.6869A>G p.Y2290C | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MAGEC2 | c.875G>C p.S292T | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- MAP3K5 | c.4037G>A p.R1346H | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- PABPC1 | c.624G>T p.K208N | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.093); called by muse, mutect2
- PCDHGA2 | c.1091C>T p.T364I | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- PLEKHG1 | c.1026C>A p.F342L | Missense Mutation (SNP) | VAF 8/119 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- PRTG | c.2214C>G p.I738M | Missense Mutation (SNP) | VAF 46/92 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- PUS3 | c.445G>C p.E149Q | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT tolerated (0.42); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- RASGEF1B | c.1417G>C p.V473L | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); called by muse, varscan2
- RNF128 | c.332G>A p.R111K | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- SLC16A5 | c.1317C>G p.F439L | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (0.69); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SYNE1 | c.4925G>C p.R1642T (on ENST00000367255 / NM_182961.4; = p.R1649T on NM_033071.3) | Missense Mutation (SNP) | VAF 44/248 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- TPH2 | c.445G>C p.E149Q | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- TPTE | c.1028-1G>A p.X343_splice (on ENST00000618007 / NM_199261.4; = p.X325_splice on NM_199259.4) | Splice Site (SNP) | VAF 16/59 reads (27%) | called by muse, mutect2, varscan2
- TRGV2 | c.279G>C p.R93S | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT tolerated (0.7); PolyPhen benign (0.108); called by muse, mutect2
- USP19 | c.695G>C p.G232A | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by mutect2, varscan2
- ZC4H2 | c.182C>T p.A61V | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ZNF749 | c.122T>A p.F41Y | Missense Mutation (SNP) | VAF 10/249 reads (4%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.945); called by muse, mutect2
- AP1G1 | c.24G>T p.R8= | Silent (SNP) | VAF 14/41 reads (34%) | called by muse, mutect2, varscan2
- APOB | c.10590G>T p.V3530= | Silent (SNP) | VAF 72/142 reads (51%) | called by muse, mutect2, varscan2
- CABIN1 | c.4959C>T p.F1653= | Silent (SNP) | VAF 28/38 reads (74%) | catalogued as COSV54087521; called by muse, mutect2, varscan2
- CREB5 | c.225C>T p.F75= (on ENST00000357727 / NM_182898.4; = p.F68= on NM_004904.3) | Silent (SNP) | VAF 80/187 reads (43%) | called by muse, mutect2, varscan2
- DSTYK | c.2310C>T p.S770= | Silent (SNP) | VAF 23/59 reads (39%) | catalogued as COSV100904533; called by muse, mutect2, varscan2
- DYRK3 | c.1227C>T p.F409= | Silent (SNP) | VAF 51/174 reads (29%) | catalogued as rs146045931; called by muse, mutect2, varscan2
- ERMARD | c.1908C>T p.Y636= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as rs151319719; called by muse, mutect2, varscan2
- HDAC8 | c.843A>G p.P281= | Silent (SNP) | VAF 18/108 reads (17%) | called by muse, mutect2, varscan2
- JPH4 | c.1644G>A p.E548= | Silent (SNP) | VAF 67/128 reads (52%) | catalogued as COSV58112608; called by muse, mutect2, varscan2
- OBSCN | c.11226G>A p.P3742= | Silent (SNP) | VAF 38/201 reads (19%) | catalogued as rs368849874, COSV52791382; called by muse, mutect2, varscan2
- OR5L1 | c.615G>A p.L205= | Silent (SNP) | VAF 15/122 reads (12%) | catalogued as COSV100450195; called by muse, mutect2, varscan2
- PCDHB5 | c.1662C>T p.N554= | Silent (SNP) | VAF 8/153 reads (5%) | catalogued as rs368703808; called by muse, mutect2
- PCLO | c.5892G>A p.T1964= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as rs375495710; called by muse, varscan2
- PLA2G4D | c.807C>G p.L269= | Silent (SNP) | VAF 58/142 reads (41%) | called by muse, mutect2, varscan2
- SERPINB8 | c.817C>T p.L273= | Silent (SNP) | VAF 20/73 reads (27%) | called by muse, mutect2, varscan2
- SLC16A5 | c.462C>T p.L154= | Silent (SNP) | VAF 14/59 reads (24%) | called by muse, mutect2, varscan2
- SLC16A5 | c.756C>T p.F252= | Silent (SNP) | VAF 19/77 reads (25%) | catalogued as COSV61675550, COSV61675960; called by muse, mutect2, varscan2
- SLC16A5 | c.936C>G p.L312= | Silent (SNP) | VAF 28/147 reads (19%) | called by muse, mutect2, varscan2
- SLC39A10 | c.1530C>T p.I510= | Silent (SNP) | VAF 17/60 reads (28%) | called by muse, mutect2, varscan2
- USPL1 | c.3057T>C p.H1019= | Silent (SNP) | VAF 14/98 reads (14%) | called by muse, mutect2, varscan2
- XKR4 | c.1029C>T p.L343= | Silent (SNP) | VAF 36/47 reads (77%) | catalogued as COSV59313456; called by muse, mutect2, varscan2
- CTBP2 | c.58+11325G>A | Intron (SNP) | VAF 4/31 reads (13%) | catalogued as rs762107393, COSV100456473; called by mutect2, varscan2
- DST | c.4297-4968G>A | Intron (SNP) | VAF 16/43 reads (37%) | called by muse, mutect2, varscan2
- IGHM | c.1300+20C>T | Intron (SNP) | VAF 61/107 reads (57%) | catalogued as rs553799938; called by muse, mutect2, varscan2
